Somatic mutation profile of tumor specimen 4976cbf9-cad4-48ce-b234-622c70 (aliquot 4976cbf9-cad4-48ce-b234-622c70_D6) from CPTAC case 05CO048, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 4976cbf9-cad4-48ce-b234-622c70: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3de35423-146a-461e-9097-ae8dfb96ba00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4f120ff2-622f-4dfd-876e-46e788 (Blood Derived Normal), aliquot 4f120ff2-622f-4dfd-876e-46e788_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed00e5ff-e60b-4f35-bbd2-0bc884a4e713

The open-access MAF lists 1,692 somatic variants for this specimen: 1,127 protein-altering or splice-affecting, 351 silent, 214 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 761, Silent 351, Frame Shift Del 243, Intron 112, Frame Shift Ins 56, Nonsense Mutation 37, 3'UTR 37, 5'UTR 23, 5'Flank 17, RNA 16, Splice Site 15, Splice Region 12.

Variants (750 of 1,692; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5178-1G>A p.X1726_splice | Splice Site (SNP) | VAF 92/335 reads (27%) | catalogued as rs1555105579, COSV53737155, COSV99588039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BBS10 | c.235dup p.T79Nfs*17 | Frame Shift Ins (INS) | VAF 42/170 reads (25%) | catalogued as rs760693838; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.5351del p.N1784Tfs*7 | Frame Shift Del (DEL) | VAF 62/301 reads (21%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CFTR | c.2052del p.K684Nfs*38 | Frame Shift Del (DEL) | VAF 78/462 reads (17%) | catalogued as rs121908746; ClinVar: pathogenic; called by pindel, varscan2
- DICER1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 26/520 reads (5%) | catalogued as rs1131691211, COSV100601828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GAA | c.258del p.N87Tfs*55 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HSPG2 | c.1219del p.Q407Rfs*3 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 77/194 reads (40%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 54/184 reads (29%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 41/190 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel
- SMAD4 | c.1228_1229del p.Q410Efs*18 | Frame Shift Del (DEL) | VAF 117/227 reads (52%) | catalogued as rs1555686608; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TCIRG1 | c.480dup p.P161Afs*66 | Frame Shift Ins (INS) | VAF 25/140 reads (18%) | catalogued as rs1554995341; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA8 | c.1461A>C p.K487N | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99284471; called by muse, varscan2
- ABCC11 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1242716213, COSV100750661; called by muse, mutect2, varscan2
- ABCG2 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs769734146; called by muse, mutect2
- ABHD17A | c.409C>T p.R137C (on ENST00000292577 / NM_001130111.2; = p.R188C on NM_031213.4) | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs1215002146; called by muse, mutect2, varscan2
- ACHE | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs1343252087, COSV53817414; called by muse, mutect2, varscan2
- ACLY | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1555632481, COSV100709644; called by muse, mutect2, varscan2
- ADAD1 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs1168132471; called by muse, mutect2, varscan2
- ADAMTS12 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771662441, COSV61254693; called by muse, mutect2, varscan2
- ADAMTS5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs1214733599, COSV53184219; called by muse, mutect2
- ADAMTS5 | c.145del p.E49Rfs*117 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as COSV53186404; called by mutect2, pindel, varscan2
- ADD2 | c.1906A>G p.T636A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs145267894; called by muse, mutect2, varscan2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1189742043; called by mutect2, varscan2
- ADRA2C | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs748739272; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 35/180 reads (19%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AFF3 | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 39/165 reads (24%) | catalogued as rs1469868233, COSV57854798, COSV57875429; called by muse, mutect2, varscan2
- AJM1 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs1395648982; called by muse, varscan2
- AL592490.1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271532133, COSV69427654; called by muse, mutect2, varscan2
- ALDH16A1 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149300233; called by muse, mutect2, varscan2
- ALDH1B1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369090946, COSV66619607; called by muse, mutect2, varscan2
- ALG5 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV99523910; called by muse, mutect2, varscan2
- AMER2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV63438610; called by muse, mutect2, varscan2
- AMIGO3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs772464782; called by muse, mutect2, varscan2
- ANK2 | c.8266G>T p.D2756Y | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs755000290; called by muse, mutect2, varscan2
- ANK2 | c.11060G>A p.C3687Y | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs143803967; called by muse, mutect2, varscan2
- ANKRD10 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs769412488; called by muse, mutect2, varscan2
- ANKRD33 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs745430001; called by muse, mutect2, varscan2
- ANKRD33B | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1176039813; called by muse, mutect2, varscan2
- ANO4 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs966354910, COSV73332891; called by muse, mutect2
- APMAP | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376711640; called by muse, mutect2, varscan2
- APOA5 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1205293123; called by muse, mutect2, varscan2
- APOB | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181737266; ClinVar: likely benign; called by muse, varscan2
- APOE | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs1396111554; called by muse, mutect2, varscan2
- ARGLU1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 53/256 reads (21%) | catalogued as rs372226737; called by muse, mutect2, varscan2
- ARHGEF1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs1555849325, COSV100529055; called by muse, varscan2
- ARHGEF11 | c.4385C>T p.T1462M | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747398529, COSV100168889; called by muse, mutect2, varscan2
- ARID1A | c.6738G>T p.E2246D | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1457651807; called by muse, mutect2, varscan2
- ARRB2 | c.1083C>T p.A361= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs376581927; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 96/316 reads (30%) | catalogued as rs753865255; called by mutect2, varscan2
- ASCC3 | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as COSV100226088; called by muse, mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 54/302 reads (18%) | catalogued as rs1558150870; called by mutect2, varscan2
- ATAD3A | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs1463982607; called by muse, varscan2
- ATF3 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1459940175; called by muse, mutect2, varscan2
- ATF5 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs529451197; called by muse, mutect2, varscan2
- ATM | c.1156del p.R386Gfs*4 | Frame Shift Del (DEL) | VAF 79/273 reads (29%) | catalogued as CM149293, COSV53759124; called by mutect2, pindel, varscan2
- ATP12A | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs759125879, COSV54525072; called by muse, mutect2, varscan2
- ATP1A1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747283959; called by muse, mutect2
- ATP2C2 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746453029; called by muse, varscan2
- AXL | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs143593613; called by muse, mutect2, varscan2
- B2M | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62562913, COSV62563197; called by muse, mutect2, varscan2
- B3GNTL1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs1415256532, COSV57949750; called by muse, mutect2, varscan2
- BAHCC1 | c.6884del p.P2295Rfs*157 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs1555659328, COSV100311941; called by mutect2, pindel, varscan2
- BAIAP3 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.167); catalogued as rs1198146154; called by muse, mutect2, varscan2
- BAZ1B | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1554573050, COSV59993970; called by muse, mutect2, varscan2
- BBS9 | c.1966C>T p.R656W (on ENST00000242067 / NM_001348036.1; = p.R616W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/450 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762045410, COSV54193988; called by mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 28/75 reads (37%) | catalogued as rs768244116; called by mutect2, varscan2
- BDH1 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767131775, COSV64018892; called by muse, mutect2, varscan2
- BIRC6 | c.11820del p.R3941Gfs*7 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | catalogued as COSV101427757; called by mutect2, pindel, varscan2
- BPIFC | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs369957427; called by muse, mutect2, varscan2
- BRWD3 | c.2519C>G p.P840R | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as COSV100956504, COSV64754497; called by muse, mutect2, varscan2
- BSN | c.7903C>T p.R2635C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762860512, COSV56513493; called by muse, mutect2, varscan2
- C12orf66 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1256138461, COSV61323750, COSV61324643; called by muse, mutect2, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 69/248 reads (28%) | catalogued as rs780875081; called by mutect2, varscan2
- C18orf63 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs1465838416; called by muse, mutect2
- C4orf54 | c.4488del p.N1497Tfs*13 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | catalogued as rs1249107798; called by mutect2, pindel, varscan2
- CA10 | c.69G>T p.Q23H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as COSV99562059; called by muse, mutect2, varscan2
- CA2 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1192862419; called by muse, mutect2, varscan2
- CACNA1G | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1264202646; called by muse, mutect2, varscan2
- CACNB3 | c.472+13del | Splice Region (DEL) | VAF 12/62 reads (19%) | catalogued as rs778256532; called by mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD14 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100712519; called by muse, mutect2, varscan2
- CARM1 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV53402665; called by muse, mutect2, varscan2
- CARMIL1 | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.2); catalogued as rs754280097, COSV61517567; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | catalogued as rs770159446; called by mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CBX6 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53322150; called by muse, mutect2, varscan2
- CBX7 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV53358663; called by muse, mutect2, varscan2
- CCDC78 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1427799576; called by muse, mutect2, varscan2
- CCDC93 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as rs368763445; called by muse, mutect2, varscan2
- CCIN | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV58724813; called by muse, mutect2, varscan2
- CCKBR | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV58100535, COSV58103786; called by muse, varscan2
- CCM2L | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1568910274, COSV99395434; called by muse, mutect2, varscan2
- CD276 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1446179438, COSV59203428, COSV59204018; called by muse, mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs762035931; called by mutect2, pindel, varscan2
- CDCA4 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs1279402601; called by muse, varscan2
- CDH12 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs760055627, COSV66389462; called by muse, mutect2, varscan2
- CDH15 | c.1537dup p.H513Pfs*144 | Frame Shift Ins (INS) | VAF 42/186 reads (23%) | catalogued as rs763850576; called by mutect2, varscan2
- CDH23 | c.6157G>A p.A2053T | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs375845975; called by muse, mutect2, varscan2
- CECR2 | c.3166G>A p.A1056T (on ENST00000342247 / NM_001290047.2; = p.A872T on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs370892204; called by muse, mutect2, varscan2
- CELSR3 | c.4625C>T p.S1542L | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV50847663; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP112 | c.2648G>A p.R883Q (on ENST00000392769 / NM_001353127.1; = p.R139Q on NM_001037325.3) | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.947); catalogued as rs753950356; called by muse, mutect2, varscan2
- CEP128 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.242); catalogued as rs779458155, COSV53673343; called by muse, mutect2, varscan2
- CFAP74 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs747666437; called by muse, mutect2, varscan2
- CFAP99 | c.224C>T p.A75V (on ENST00000506607; = p.A560V on NM_001193282.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1209006878; called by muse, mutect2, varscan2
- CFD | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767989615; called by muse, mutect2, varscan2
- CHEK2 | c.1732C>T p.R578C (on ENST00000382580 / NM_001005735.2; = p.R535C on NM_007194.4) | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs576248104, COSV100101589; ClinVar: uncertain significance; called by muse, varscan2
- CHGB | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as rs553869356, COSV66759863; called by muse, mutect2, varscan2
- CLEC4D | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs374210290, COSV100222924, COSV55227887; called by muse, mutect2, varscan2
- CLK4 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.893); catalogued as rs1173954412; called by muse, mutect2, varscan2
- CLN8 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58670003; called by muse, mutect2
- CLYBL | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | catalogued as rs538135354; called by mutect2, varscan2
- CNTLN | c.3471G>T p.Q1157H | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV52080013; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP3 | c.2944dup p.V982Gfs*4 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | catalogued as rs763585044; called by mutect2, varscan2
- CNTNAP4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1014910351, COSV56669618; called by muse, mutect2, varscan2
- COL18A1 | c.4173del p.G1392Afs*54 (on ENST00000359759 / NM_130444.3; = p.G1157Afs*54 on NM_030582.4) | Frame Shift Del (DEL) | VAF 76/169 reads (45%) | catalogued as rs749541171; called by mutect2, varscan2
- COL4A2 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.121); catalogued as rs368382267; called by muse, mutect2, varscan2
- COL5A1 | c.5294G>A p.R1765H | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs150608071; called by muse, mutect2, varscan2
- COLEC11 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748463932, COSV99362764; called by muse, mutect2, varscan2
- COP1 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58177776; called by muse, varscan2
- CPAMD8 | c.4097C>T p.A1366V (on ENST00000651564; = p.A1319V on NM_015692.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs775677902; called by muse, mutect2, varscan2
- CRB1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 68/778 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as rs1464001763; called by muse, mutect2
- CSMD1 | c.1226C>T p.A409V (on ENST00000520002; = p.A408V on NM_033225.6) | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.914); catalogued as rs912861753; called by muse, varscan2
- CSPG4 | c.3970C>T p.R1324C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs763848998, COSV57895400; called by muse, mutect2, varscan2
- CSPG4 | c.2501T>G p.L834R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771903812; called by muse, mutect2, varscan2
- CSPP1 | c.2100G>A p.M700I (on ENST00000676605; = p.M659I on NM_024790.6) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99138100; called by muse, mutect2, varscan2
- CUBN | c.2731G>A p.V911M | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs768821054, COSV100912217; called by muse, varscan2
- CUL2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1303633670; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | catalogued as rs772257590; called by mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP2D6 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.456); catalogued as rs1198309616; called by muse, mutect2, varscan2
- CYTL1 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs761041037; called by muse, mutect2, varscan2
- DBH | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs141137998; called by muse, mutect2, varscan2
- DBX2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs929775800; called by muse, mutect2, varscan2
- DBX2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1271273960; called by muse, mutect2, varscan2
- DCHS2 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.079); catalogued as rs959418043; called by muse, varscan2
- DDR1 | c.2570C>T p.A857V (on ENST00000324771; = p.A820V on NM_001954.4) | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs764775490; called by muse, mutect2, varscan2
- DDR2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 78/415 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV63372301; called by muse, mutect2, varscan2
- DDX1 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51838143; called by muse, mutect2
- DDX51 | c.495dup p.F166Vfs*19 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | catalogued as rs749572607; called by mutect2, varscan2
- DEAF1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.51); catalogued as rs371722695; called by muse, mutect2, varscan2
- DENND3 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200436717, COSV99370677; called by muse, mutect2, varscan2
- DGKK | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 44/99 reads (44%) | catalogued as COSV65706472; called by muse, mutect2, varscan2
- DHRSX | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV58133901; called by muse, mutect2, varscan2
- DIDO1 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs767278364; called by muse, mutect2, varscan2
- DIP2A | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV59473679; called by muse, mutect2, varscan2
- DMD | c.5788C>T p.R1930C | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1295144399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMWD | c.1366del p.L456Wfs*203 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs746317972; called by mutect2, varscan2
- DNAH10 | c.629del p.L210Cfs*40 (on ENST00000409039; = p.L149Cfs*40 on NM_207437.3) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs757790699; called by mutect2, pindel, varscan2
- DNAH10 | c.2950C>T p.R984W (on ENST00000409039; = p.R923W on NM_207437.3) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs138047908; called by muse, mutect2, varscan2
- DNAH11 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.585); catalogued as rs557408462; called by muse, mutect2, varscan2
- DNAH3 | c.9632C>T p.A3211V | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs545853424; called by muse, mutect2, varscan2
- DNAH6 | c.6229C>T p.R2077C | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs576447190, COSV52849308; called by muse, mutect2, varscan2
- DNAH7 | c.6296G>A p.R2099Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs373086090; called by muse, varscan2
- DNAH7 | c.2065T>C p.C689R | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs773645777, COSV56776645; called by muse, varscan2
- DNAJC18 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs377218182; called by mutect2, varscan2
- DNMT1 | c.4435G>A p.V1479M | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs781301028, COSV61576733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs778009798, COSV56529714, COSV99812979; called by muse, mutect2, varscan2
- DOCK9 | c.4002dup p.T1335Yfs*4 (on ENST00000376460 / NM_001366676.2; = p.T1336Yfs*4 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 25/129 reads (19%) | catalogued as rs1344550381; called by mutect2, varscan2
- DSG2 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs368257724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP5 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100851839; called by muse, mutect2, varscan2
- DYNC2H1 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as COSV62090638; called by muse, mutect2, varscan2
- EGFLAM | c.3004G>A p.V1002M (on ENST00000354891 / NM_001205301.2; = p.V994M on NM_152403.4) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs372253494; called by muse, mutect2, varscan2
- EIF2AK4 | c.281del p.N94Mfs*13 | Frame Shift Del (DEL) | VAF 53/99 reads (54%) | catalogued as COSV55466133; called by mutect2, pindel, varscan2
- EIPR1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376371713; called by mutect2, varscan2
- ELAC2 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV62033178; called by muse, mutect2, varscan2
- EML1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1342349380; called by muse, mutect2, varscan2
- EPB41L3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs750621088, COSV59455576; called by muse, mutect2, varscan2
- EPB41L4A | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745388190, COSV54874560; called by muse, mutect2, varscan2
- ERCC6L2 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs368747018, COSV56632074; called by muse, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 62/222 reads (28%) | catalogued as rs765136869; called by mutect2, varscan2
- EXD3 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1414308965; called by muse, mutect2, varscan2
- EXOSC10 | c.2392C>T p.R798* (on ENST00000376936 / NM_001001998.3; = p.R773* on NM_002685.4) | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as rs1169738528; called by muse, mutect2, varscan2
- FAM124A | c.268C>T p.R90W (on ENST00000322475 / NM_001242312.2; = p.R126W on NM_145019.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs775685213, COSV54474785; called by muse, mutect2, varscan2
- FAM13A | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs200713682, COSV99983491; called by muse, mutect2, varscan2
- FAM13C | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as rs1199158383, COSV53252463; called by muse, mutect2, varscan2
- FAM47C | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs782633837, COSV63724476; called by muse, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs757443519; called by mutect2, varscan2
- FAT3 | c.12055G>A p.V4019M | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV53114491; called by muse, mutect2, varscan2
- FAT4 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV67891450; called by muse, mutect2, varscan2
- FAT4 | c.5444G>A p.R1815H | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774484692, COSV58675150, COSV58684354; called by muse, mutect2, varscan2
- FBN3 | c.4802G>A p.R1601H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs771565430, COSV54461878; called by muse, mutect2, varscan2
- FBXL18 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs770667633, COSV66107451; called by muse, mutect2, varscan2
- FBXL7 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767178690, COSV61654436; called by muse, mutect2, varscan2
- FER1L5 | c.3800C>T p.T1267M (on ENST00000623019; = p.T1240M on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs1409165315; called by muse, varscan2
- FEZ1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs867006645, COSV54028631; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLCN | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs771653740, COSV53262485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.10872G>C p.E3624D | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.194); catalogued as rs199933055, COSV64246485; called by mutect2, varscan2
- FLG | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs765277211; called by muse, varscan2
- FOXD4L3 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as COSV61551680; called by muse, mutect2, varscan2
- FSCN2 | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1347816093; called by muse, mutect2, varscan2
- FSCN3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs760881450, COSV50001380; called by muse, mutect2, varscan2
- FUT2 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs146216418; called by muse, mutect2, varscan2
- FUT4 | c.741del p.D248Tfs*48 | Frame Shift Del (DEL) | VAF 53/235 reads (23%) | catalogued as rs746338726; called by mutect2, pindel, varscan2
- FZD10 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.313); catalogued as COSV57472441, COSV99969342; called by muse, mutect2, varscan2
- G6PD | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782583168; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1553309006; called by mutect2, varscan2
- GAS1 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs1472763904, CM103792; called by mutect2, varscan2
- GDPD5 | c.711del p.M238Cfs*78 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV61129354; called by mutect2, varscan2
- GGT5 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770771145, COSV54071181; called by muse, mutect2, varscan2
- GGTLC1 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs1486140075; called by mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs750227570; called by mutect2, varscan2
- GLI3 | c.3453del p.E1152Rfs*54 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as COSV67892282; called by mutect2, pindel, varscan2
- GMEB2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs747475974, COSV56608001, COSV56608810; called by muse, mutect2, varscan2
- GMPPA | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756708119, COSV58007713; called by muse, mutect2, varscan2
- GORASP1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs746306013, COSV56534526; called by muse, mutect2, varscan2
- GP6 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1410354161; called by muse, mutect2, varscan2
- GPCPD1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1373395969, COSV66831188; called by muse, mutect2, varscan2
- GPR1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.181); catalogued as rs1392133952; called by muse, varscan2
- GPR135 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs575016635, COSV67749669, COSV67749833; called by muse, mutect2, varscan2
- GPR135 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as COSV67749674; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GRB14 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs138078116, COSV55736441; called by muse, mutect2, varscan2
- GRIN2A | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1354238435, COSV58046734; called by muse, varscan2
- GRIN2C | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149835650, COSV99501550; called by muse, mutect2, varscan2
- GRIN2D | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54380226; called by muse, mutect2, varscan2
- GRINA | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs998426820, COSV57592098; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | catalogued as COSV58842099; called by mutect2, pindel
- GSX1 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766872119, COSV57232528; called by muse, mutect2, varscan2
- GUCY1A2 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1259379286, COSV56489596; called by muse, mutect2, varscan2
- GYPC | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs571586275; called by muse, mutect2, varscan2
- HDAC4 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs760502899; called by muse, mutect2, varscan2
- HECTD4 | c.12394C>T p.R4132W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66392274; called by muse, mutect2, varscan2
- HELZ | c.4988C>T p.S1663L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV100698451; called by muse, mutect2, varscan2
- HERPUD1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs778038556; called by mutect2, varscan2
- HIP1R | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs760394973, COSV53444775; called by muse, mutect2, varscan2
- HLCS | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 40/163 reads (25%) | catalogued as COSV60793784; called by muse, mutect2, varscan2
- HMX3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.037); catalogued as COSV63501965; called by muse, mutect2, varscan2
- HNRNPDL | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs988284711, COSV55023147; called by muse, mutect2, varscan2
- HNRNPL | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as rs747525290, COSV55490907; called by muse, mutect2, varscan2
- HNRNPLL | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1376176575; called by muse, mutect2, varscan2
- HS3ST1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74785727, COSV50024457; called by muse, mutect2, varscan2
- HSPB2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs192172142; called by muse, mutect2, varscan2
- HTR2A | c.1289del p.K430Rfs*19 | Frame Shift Del (DEL) | VAF 56/266 reads (21%) | catalogued as rs1398128295; called by mutect2, pindel, varscan2
- HUNK | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs376957999; called by muse, mutect2, varscan2
- IGHV3-49 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as rs782186206; called by muse, mutect2, varscan2
- IGSF8 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs780189402, COSV58758476; called by muse, mutect2, varscan2
- IGSF9 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201134918; called by muse, mutect2, varscan2
- ILDR1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56553985; called by muse, mutect2, varscan2
- INPP5J | c.1820G>A p.R607H (on ENST00000331075 / NM_001284285.2; = p.R239H on NM_001002837.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753205592, COSV100458986; called by muse, mutect2, varscan2
- INTS2 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.969); catalogued as rs781406399; called by muse, mutect2, varscan2
- IRAG1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs754927600; called by muse, mutect2, varscan2
- ITGB5 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs200612182; called by muse, mutect2, varscan2
- ITIH5 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368637112; called by mutect2, varscan2
- JRK | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs781893617; called by muse, mutect2, varscan2
- JRKL | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs769442078; called by muse, mutect2, varscan2
- KBTBD13 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs749801900, COSV71351601; called by muse, mutect2, varscan2
- KCNH6 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs759800226; called by muse, mutect2, varscan2
- KCNS1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100066957; called by muse, mutect2
- KCP | c.3672G>A p.T1224= (on ENST00000620378; = p.T1348= on NM_001366122.1) | Splice Region (SNP) | VAF 7/110 reads (6%) | catalogued as rs1401349930; called by muse, mutect2
- KDM3B | c.4483C>T p.R1495* | Nonsense Mutation (SNP) | VAF 46/187 reads (25%) | catalogued as COSV58690312; called by muse, mutect2, varscan2
- KDM6B | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.924); catalogued as rs774548555, COSV54687030; called by muse, mutect2, varscan2
- KIAA0319L | c.399dup p.F134Ifs*6 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | catalogued as rs1383796563; called by mutect2, varscan2
- KIAA1109 | c.8482A>G p.T2828A | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52664771; called by muse, mutect2, varscan2
- KIAA1217 | c.1225T>C p.S409P | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as rs750864115; called by muse, mutect2, varscan2
- KIF26B | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773883282, COSV63641009; called by muse, mutect2, varscan2
- KIF26B | c.3658del p.R1220Gfs*43 | Frame Shift Del (DEL) | VAF 109/232 reads (47%) | catalogued as COSV104426255; called by mutect2, pindel, varscan2
- KLC4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs773059424; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 50/172 reads (29%) | catalogued as rs1227078726; called by mutect2, varscan2
- KLHL38 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 150/327 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs369630981; called by muse, mutect2, varscan2
- KLKB1 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52994792; called by muse, mutect2, varscan2
- KPNA7 | c.184dup p.T62Nfs*13 | Frame Shift Ins (INS) | VAF 29/120 reads (24%) | catalogued as rs746637129; called by mutect2, pindel, varscan2
- KRT28 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768445733, COSV60686608; called by muse, varscan2
- LALBA | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs558586421, COSV56396651; called by muse, mutect2, varscan2
- LAMP1 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58148824; called by muse, mutect2, varscan2
- LARP4 | c.1118del p.N373Ifs*3 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as rs1179425728; called by mutect2, pindel, varscan2
- LAX1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs779557724, COSV65848782; called by muse, mutect2, varscan2
- LCT | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs751898984, COSV51548234; called by muse, mutect2, varscan2
- LHX2 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as rs764015032; called by muse, mutect2, varscan2
- LIMS1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs1192098049; called by muse, mutect2, varscan2
- LMCD1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs973202385, COSV50089268; called by muse, mutect2, varscan2
- LMO7 | c.3706C>T p.R1236C (on ENST00000357063; = p.R917C on NM_005358.5) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373742063; called by muse, mutect2, varscan2
- LRP1B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs776305678, COSV67188037; called by muse, mutect2, varscan2
- LRRC36 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373608861, COSV99339077; called by muse, mutect2, varscan2
- LRRC8A | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs753358771; called by muse, mutect2, varscan2
- LRRIQ1 | c.1103del p.K368Rfs*4 | Frame Shift Del (DEL) | VAF 34/269 reads (13%) | catalogued as rs755230729; called by mutect2, pindel, varscan2
- LRTOMT | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53825358; called by muse, mutect2, varscan2
- LSM11 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs769842787; called by muse, mutect2, varscan2
- LTBP4 | c.3406C>T p.R1136* (on ENST00000308370 / NM_001042544.1; = p.R1099* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs1028864026; called by muse, mutect2, varscan2
- MAB21L1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59788111; called by muse, mutect2, varscan2
- MADD | c.2412-1G>T p.X804_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV60624242; called by muse, mutect2, varscan2
- MAGEL2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1248852458, COSV58569352; called by muse, mutect2, varscan2
- MAJIN | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57263406; called by muse, mutect2, varscan2
- MAN1B1 | c.1014dup p.L339Afs*18 | Frame Shift Ins (INS) | VAF 40/204 reads (20%) | catalogued as rs752359237; called by mutect2, varscan2
- MANEA | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 24/527 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV62589246; called by muse, mutect2
- MARK2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158864; called by muse, mutect2, varscan2
- MAS1L | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs770468152, COSV65808917; called by muse, mutect2, varscan2
- MDGA2 | c.2945C>T p.S982L (on ENST00000399232 / NM_001113498.2; = p.S684L on NM_182830.4) | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as COSV62119807; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs750092100; called by mutect2, varscan2
- MEGF11 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759126291; called by muse, mutect2, varscan2
- MGAM | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs756381544, COSV101527347; called by muse, varscan2
- MIDEAS | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54093322; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 50/84 reads (60%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MMP24 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs369700691; called by muse, mutect2, varscan2
- MMP27 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1275390005; called by muse, mutect2, varscan2
- MMP9 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs776052269, COSV100812351; called by muse, varscan2
- MOV10L1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as rs41311449, COSV99435080; called by muse, mutect2, varscan2
- MRTFB | c.2779A>G p.I927V (on ENST00000571589 / NM_001365412.2; = p.I877V on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs928142974; called by muse, mutect2, varscan2
- MTFR1L | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749895074, COSV65356073; called by muse, mutect2, varscan2
- MTMR6 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760490843; called by muse, mutect2, varscan2
- MUC19 | c.424del p.Y142Mfs*99 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | catalogued as rs776041179; called by mutect2, pindel, varscan2
- MYBPHL | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs986151299; called by muse, varscan2
- MYF5 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1161178069, COSV57355123; called by muse, mutect2, varscan2
- MYH6 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs762303505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773009513, CM132339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.3610-8T>A | Splice Region (SNP) | VAF 21/84 reads (25%) | catalogued as rs765041022, COSV52751650; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18A | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs757196330, COSV62870738; called by muse, mutect2, varscan2
- MYO19 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215790560; called by muse, mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | catalogued as COSV68685202; called by mutect2, pindel, varscan2
- MYOM2 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs763643341, CM147958, COSV50705013; called by muse, mutect2, varscan2
- MYORG | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898673; called by mutect2, varscan2
- NAALAD2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs915139665, COSV58958529; called by muse, mutect2, varscan2
- NACAD | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV71989493; called by muse, mutect2, varscan2
- NANOG | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs745903026; called by muse, mutect2, varscan2
- NBAS | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370106017; called by muse, mutect2, varscan2
- NBEAL2 | c.7061G>A p.R2354H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs371473167; called by muse, mutect2, varscan2
- NCOA6 | c.1753A>G p.M585V | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs558989884, COSV62863301; called by muse, varscan2
- NCOR1 | c.5428C>T p.P1810S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.979); catalogued as rs755037174; called by muse, mutect2, varscan2
- NDUFS7 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1175269673; called by muse, mutect2, varscan2
- NDUFS7 | c.456-3C>T | Splice Region (SNP) | VAF 8/103 reads (8%) | catalogued as rs1406236521; called by muse, mutect2
- NEB | c.7685A>G p.H2562R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs759327402; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NEURL4 | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs752623474, COSV59747822; called by muse, mutect2, varscan2
- NIF3L1 | c.811del p.R271Dfs*3 (on ENST00000409020 / NM_001369444.1; = p.R244Dfs*3 on NM_021824.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as COSV62899968; called by mutect2, pindel, varscan2
- NIM1K | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); catalogued as COSV58146968; called by muse, mutect2, varscan2
- NKD2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs544544673; called by muse, varscan2
- NOC4L | c.907dup p.X303_splice | Splice Site (INS) | VAF 8/32 reads (25%) | catalogued as rs765400964; called by mutect2, varscan2
- NOS1AP | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100723481; called by muse, mutect2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NPR1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866171506, COSV100903833; called by muse, mutect2, varscan2
- NRP1 | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.752); catalogued as rs750320738, COSV55160209; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs1285800435, COSV58459244, COSV58493099; called by muse, mutect2, varscan2
- NRXN2 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs141459078; called by muse, mutect2, varscan2
- NSUN2 | c.2185_2188del p.D729Mfs*3 | Frame Shift Del (DEL) | VAF 98/246 reads (40%) | catalogued as rs781120914; called by mutect2, pindel, varscan2
- NSUN5 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376143212; called by muse, mutect2, varscan2
- NUTM2A | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs565239711; called by muse, mutect2, varscan2
- NXF1 | c.1462-1G>A p.X488_splice | Splice Site (SNP) | VAF 29/139 reads (21%) | catalogued as COSV99586432; called by muse, mutect2, varscan2
- OBSCN | c.8642C>T p.A2881V | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.9); catalogued as COSV52765376; called by mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs762005098; called by mutect2, varscan2
- OBSCN | c.22507dup p.L7503Pfs*27 | Frame Shift Ins (INS) | VAF 15/100 reads (15%) | catalogued as rs755333505; called by mutect2, pindel, varscan2
- OPN1SW | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs777541057, COSV50822642; called by muse, mutect2, varscan2
- OPRK1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as rs762364309, COSV55568152, COSV55570047; called by muse, mutect2, varscan2
- OR10S1 | c.762del p.C255Afs*39 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs772207982, COSV73342953; called by mutect2, pindel, varscan2
- OR1N1 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV59195505; called by muse, mutect2, varscan2
- OR2S2 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs750682972, COSV59529677; called by muse, mutect2, varscan2
- OR4C13 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as rs267602933; called by mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 23/172 reads (13%) | catalogued as rs201077183; called by mutect2, varscan2
- OSBPL10 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs751308846, COSV101158686; called by muse, mutect2, varscan2
- OTOR | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs760783446; called by muse, mutect2, varscan2
- P2RY14 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752336571; called by muse, mutect2, varscan2
- P2RY8 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs774739464, COSV101184242; called by muse, mutect2, varscan2
- PAF1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262999119, COSV55393506; called by muse, mutect2, varscan2
- PALB2 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs786203176, COSV55164012; ClinVar: uncertain significance; called by muse, mutect2
- PANX2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as COSV50296144; called by muse, mutect2, varscan2
- PAPPA | c.2570C>T p.T857M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374066435; called by muse, mutect2, varscan2
- PAPPA2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100866766; called by muse, mutect2, varscan2
- PCDH8 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs778040396, COSV58811765; called by muse, mutect2, varscan2
- PCDH9 | c.3155C>T p.T1052M (on ENST00000377865 / NM_203487.3; = p.T1018M on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs150709677, COSV60601477; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs558931090, COSV65368078; called by mutect2, pindel, varscan2
- PCDHB12 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); catalogued as rs1554286996, COSV53394760; called by muse, varscan2
- PCDHGA8 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as rs375160983, COSV53926197; called by muse, mutect2, varscan2
- PCDHGB7 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs747887064; called by mutect2, varscan2
- PCK2 | c.1512del p.F504Lfs*13 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as COSV53748303; called by mutect2, pindel
- PCNT | c.4180del p.E1394Rfs*21 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs755265991; called by mutect2, pindel, varscan2
- PCYOX1L | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.367); catalogued as rs187971841; called by muse, mutect2, varscan2
- PDCD5 | c.294del p.V99* | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | catalogued as rs1373819281; called by mutect2, pindel, varscan2
- PDE4A | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); catalogued as rs200646979; called by muse, mutect2, varscan2
- PDZD2 | c.5968A>G p.K1990E | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs775211087; called by muse, mutect2, varscan2
- PDZD8 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1327759087, COSV57824552, COSV57825557; called by muse, mutect2, varscan2
- PGBD5 | c.413G>A p.R138H (on ENST00000525115; = p.R207H on NM_001258311.2) | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311026622, COSV58413936; called by muse, mutect2, varscan2
- PHF19 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs779726682; called by muse, mutect2, varscan2
- PIGQ | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs1206255851; called by muse, mutect2, varscan2
- PIK3CD | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as rs370932461, COSV100740274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAA | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754016270, COSV101263518; called by muse, mutect2, varscan2
- PLEC | c.7549G>A p.A2517T (on ENST00000322810 / NM_201380.4; = p.A2407T on NM_000445.5) | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs531930290, COSV100519009; called by muse, mutect2, varscan2
- PLEC | c.3353G>A p.R1118H (on ENST00000322810 / NM_201380.4; = p.R1008H on NM_000445.5) | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781911502; called by mutect2, varscan2
- PLEKHH2 | c.4010G>A p.R1337H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372835795, COSV56750186; called by muse, mutect2, varscan2
- PLG | c.91del p.A31Lfs*16 | Frame Shift Del (DEL) | VAF 31/163 reads (19%) | catalogued as COSV99805210; called by mutect2, pindel, varscan2
- PLPPR2 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs950439217; called by muse, mutect2
- PLPPR3 | c.1198G>A p.D400N (on ENST00000520876 / NM_001270366.2; = p.D428N on NM_024888.2) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1374644453; called by muse, mutect2, varscan2
- PLXNB2 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1280294689; called by muse, mutect2, varscan2
- PML | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 110/192 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs767787538; called by muse, mutect2, varscan2
- PNKP | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 102/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs199705876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD1 | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1422842883, COSV54531771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.6088del p.A2030Pfs*18 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs1060500809; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- POLE | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1482283883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs760361713; called by muse, mutect2, varscan2
- POU4F2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1466000303; called by muse, mutect2, varscan2
- PPARGC1B | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs766455378; called by muse, mutect2, varscan2
- PPEF2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs761383219, COSV54421096; called by muse, mutect2, varscan2
- PPP1R36 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs772973762; called by muse, mutect2, varscan2
- PPP3R2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV62457005; called by muse, mutect2, varscan2
- PRKACG | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55253021, COSV99598625; called by muse, mutect2, varscan2
- PRLH | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs144703716; called by muse, mutect2, varscan2
- PROCA1 | c.805A>G p.S269G (on ENST00000439862 / NM_001366301.1; = p.S241G on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs773096567; called by muse, mutect2, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2, varscan2
- PROSER1 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.36); catalogued as rs374216828; called by muse, mutect2, varscan2
- PROSER2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs757522067; called by muse, mutect2, varscan2
- PRR12 | c.929G>A p.R310H (on ENST00000615927; = p.R1131H on NM_020719.3) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as rs758117305; called by muse, mutect2, varscan2
- PRRT4 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.957); catalogued as rs1271072024; called by muse, mutect2, varscan2
- PRSS35 | c.705del p.K235Nfs*48 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs746796662; called by mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs756013055, COSV53629833; called by pindel, varscan2
- PURG | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV53304641; called by muse, mutect2, varscan2
- RAB14 | c.105del p.K35Nfs*18 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | catalogued as rs1564320972; called by mutect2, varscan2
- RAB3IP | c.172C>T p.R58W (on ENST00000550536 / NM_175623.4; = p.R42W on NM_022456.5) | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs749687711, COSV56085347; called by muse, mutect2, varscan2
- RADIL | c.1286del p.G429Afs*6 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs768989877; called by mutect2, pindel, varscan2
- RAI2 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV58965265; called by muse, mutect2, varscan2
- RAPGEF1 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1415303385; called by muse, varscan2
- RAPGEFL1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs200106334, COSV52864836; called by muse, mutect2, varscan2
- RASAL2 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62722463; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as rs758095269; called by muse, mutect2, varscan2
- RC3H2 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV61801430; called by muse, mutect2, varscan2
- RFPL4B | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs572347418, COSV104437242; called by muse, mutect2, varscan2
- RICTOR | c.3712C>T p.R1238* | Nonsense Mutation (SNP) | VAF 101/226 reads (45%) | catalogued as COSV57116462; called by muse, mutect2, varscan2
- RIF1 | c.5291del p.K1764Rfs*8 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | catalogued as COSV99690609; called by mutect2, pindel, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF213 | c.4295G>T p.R1432L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV101509859; called by muse, mutect2, varscan2
- RNF224 | c.48del p.P18Rfs*67 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs764684501; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 27/53 reads (51%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 51/236 reads (22%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO4 | c.2245G>T p.A749S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.068); catalogued as COSV60625509; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL32 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1382444368; called by muse, mutect2, varscan2
- RPL7A | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.25); catalogued as rs781888936; called by muse, mutect2, varscan2
- RPTOR | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1255569294, COSV60818836; called by muse, mutect2, varscan2
- RSPO1 | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100740455; called by muse, mutect2, varscan2
- RTL5 | c.342del p.D115Tfs*39 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV101030454; called by mutect2, pindel, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | catalogued as rs756606313; called by mutect2, varscan2
- RYR1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs778568721, COSV100614214; called by muse, varscan2
- SAGE1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61012464; called by muse, mutect2, varscan2
- SALL3 | c.2860G>A p.A954T | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT tolerated (0.8); PolyPhen benign (0.105); catalogued as rs778959348, COSV73306695; called by muse, mutect2, varscan2
- SBF1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs769121197; called by muse, mutect2, varscan2
- SCN5A | c.4297G>A p.G1433R (on ENST00000333535 / NM_198056.3; = p.G1432R on NM_000335.5) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as rs867001670, CM136290, COSV61140071; called by muse, mutect2, varscan2
- SEC23IP | c.2272G>C p.V758L | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1452824139; called by muse, mutect2, varscan2
- SEC24A | c.3229G>A p.A1077T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV67306164; called by muse, mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, varscan2
- SEMA6C | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs587620985, COSV100501727; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 46/161 reads (29%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINA12 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs555631497, COSV100369673; called by muse, mutect2, varscan2
- SESN2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778863205, COSV99456333; called by muse, mutect2, varscan2
- SETD1B | c.4561C>T p.R1521W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs1485712294; called by muse, mutect2, varscan2
- SF3B3 | c.2773G>A p.V925I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757811305, COSV56787054; called by muse, mutect2, varscan2
- SFRP5 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV56604160; called by muse, mutect2, varscan2
- SH2B3 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1219220572; called by muse, mutect2, varscan2
- SH3D21 | c.1818del p.N607Tfs*6 (on ENST00000453908 / NM_001162530.2; = p.N496Tfs*6 on NM_024676.5) | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs774514258; called by mutect2, pindel, varscan2
- SHANK2 | c.4532C>A p.S1511Y | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53598727; called by muse, mutect2, varscan2
- SHBG | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs375872651; called by muse, mutect2, varscan2
- SHOC1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758283416; called by muse, mutect2, varscan2
- SIGLEC1 | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs372577495; called by muse, mutect2, varscan2
- SIRT1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs748394475, COSV53018314, COSV53018804; called by muse, mutect2, varscan2
- SIX3 | c.221del p.P74Rfs*177 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as rs760462666, COSV53226999; called by mutect2, pindel, varscan2
- SLC12A2 | c.1461C>G p.F487L | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772305204, COSV52471777, COSV52477300; called by muse, mutect2, varscan2
- SLC16A12 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758404955, COSV57947568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A33 | c.702del p.F234Lfs*24 | Frame Shift Del (DEL) | VAF 46/195 reads (24%) | catalogued as rs1557538606; called by mutect2, pindel, varscan2
- SLC26A4 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 47/250 reads (19%) | catalogued as CD982867, CM138988; called by mutect2, varscan2
- SLC27A4 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201409856, COSV55958630; called by muse, mutect2, varscan2
- SLC2A14 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs771821320, COSV61585468; called by muse, mutect2, varscan2
- SLC2A5 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs138176474; called by muse, mutect2, varscan2
- SLC38A10 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs201582210, COSV55844861; called by mutect2, varscan2
- SLC39A7 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs745393541, COSV63399571; called by muse, mutect2, varscan2
- SLC44A2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100213070; called by muse, mutect2, varscan2
- SMIM5 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs370000834; called by muse, mutect2, varscan2
- SNCAIP | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs199933356; called by muse, mutect2, varscan2
- SOS2 | c.2784dup p.G929Wfs*15 | Frame Shift Ins (INS) | VAF 40/144 reads (28%) | catalogued as rs1347298671; called by mutect2, varscan2
- SOX5 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1294452933, COSV58645765; called by muse, mutect2, varscan2
- SPEG | c.3907T>C p.W1303R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753649016; called by muse, mutect2, varscan2
- SPPL2C | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as COSV61292155; called by muse, mutect2, varscan2
- SPSB3 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs746457122, COSV51603157; called by muse, mutect2, varscan2
- SPTB | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144624027; called by muse, mutect2, varscan2
- SPTBN5 | c.5791C>T p.R1931C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs572942809, COSV58027273; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 64/291 reads (22%) | catalogued as rs751748506; called by mutect2, varscan2
- SRP72 | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as rs756624463; called by muse, mutect2, varscan2
- SRRM1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.034); catalogued as rs370225206; called by muse, mutect2, varscan2
- SRRM2 | c.3461T>C p.L1154S | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs1218110995; called by muse, mutect2, varscan2
- SSX7 | c.368C>G p.S123W | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99993753; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 62/274 reads (23%) | catalogued as rs752994755; called by mutect2, varscan2
- STC2 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753833263, COSV54179462; called by muse, mutect2, varscan2
- STK35 | c.358dup p.A120Gfs*73 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | catalogued as rs761062631; called by mutect2, varscan2
- STYK1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149841464; called by muse, mutect2, varscan2
- SUPV3L1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs1288855422; called by muse, mutect2
- SVEP1 | c.9218C>T p.A3073V | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as rs912108341, COSV52838268; called by muse, mutect2, varscan2
- SYDE1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770268705; called by muse, mutect2, varscan2
- SYNE1 | c.18620C>T p.T6207M (on ENST00000367255 / NM_182961.4; = p.T6136M on NM_033071.3) | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs373188583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE4 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs199938988; ClinVar: likely benign; called by muse, mutect2, varscan2
- TACR3 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV59209135; called by muse, mutect2, varscan2
- TAF6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as rs753049378; called by mutect2, varscan2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TAS2R4 | c.897del p.K299Nfs*10 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as rs749747463; called by mutect2, varscan2
- TATDN2 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs750329499; called by muse, mutect2, varscan2
- TCAIM | c.786del p.A263Qfs*14 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs1290149199; called by mutect2, pindel, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM4 | c.4654G>A p.V1552M | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs199784483; called by muse, mutect2, varscan2
- TERF2 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs769330021; called by muse, mutect2, varscan2
- TET3 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs758455484, COSV59880407; called by muse, mutect2, varscan2
- TEX52 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs748387415; called by muse, mutect2, varscan2
- TGFBR2 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99847229; called by muse, mutect2, varscan2
- TGM1 | c.718del p.R240Afs*90 | Frame Shift Del (DEL) | VAF 67/200 reads (34%) | catalogued as COSV52861850; called by mutect2, pindel, varscan2
- THSD7B | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs1341672376, COSV55716769; called by muse, mutect2, varscan2
- TIMM13 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750239213; called by muse, mutect2, varscan2
- TMEM132C | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs369408255, COSV59430525; called by muse, mutect2, varscan2
- TMEM151A | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs906630791; called by muse, mutect2, varscan2
- TMPRSS12 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1281738836, COSV101269063; called by muse, mutect2, varscan2
- TNFAIP8 | c.533T>C p.F178S | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.538); catalogued as COSV57225533; called by muse, mutect2
- TNFRSF21 | c.1712G>A p.S571N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1013686154; called by muse, mutect2, varscan2
- TNFRSF9 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs183916313; called by muse, mutect2, varscan2
- TNFRSF9 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs776774122; called by muse, mutect2, varscan2
- TNK2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99048783; called by muse, mutect2, varscan2
- TOM1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs757629430, COSV101146368; called by muse, mutect2, varscan2
- TOX2 | c.623C>T p.A208V (on ENST00000358131 / NM_001098798.2; = p.A157V on NM_032883.3) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1246753427, COSV57897779; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2
- TRAF3IP1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs985242912; called by muse, varscan2
- TRAK1 | c.1351G>A p.G451S (on ENST00000327628 / NM_001349247.2; = p.G393S on NM_014965.5) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs1245626975, COSV58256522; called by muse, mutect2
- TRERF1 | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs752393657, COSV61668200; called by muse, mutect2, varscan2
- TRIM49B | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1330498186; called by muse, mutect2, varscan2
- TRIM5 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs769401485; called by muse, mutect2, varscan2
- TRIM55 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs777018632, COSV52547166; called by muse, mutect2, varscan2
- TRIM9 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1264041827, COSV53612848; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 88/124 reads (71%) | catalogued as rs752676391; called by mutect2, varscan2
- TRPC3 | c.521G>A p.R174H (on ENST00000379645 / NM_001366479.2; = p.R101H on NM_003305.2) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436671176, COSV53371456; called by muse, mutect2, varscan2
- TRPM6 | c.3634C>A p.Q1212K | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV62524053; called by muse, mutect2, varscan2
- TRRAP | c.4276C>T p.H1426Y | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as rs782592160; called by muse, mutect2, varscan2
- TRRAP | c.11249C>T p.A3750V (on ENST00000359863 / NM_001244580.1; = p.A3721V on NM_003496.3) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs1212619468; called by muse, mutect2, varscan2
- TSC2 | c.3899T>C p.M1300T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1349341137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSN | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67605294; called by muse, mutect2, varscan2
- TSPYL2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); catalogued as rs201895359, COSV60235131, COSV60237565; called by muse, mutect2, varscan2
- TSPYL5 | c.409dup p.R137Pfs*18 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | catalogued as rs775143186; called by mutect2, pindel, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/278 reads (28%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TTN | c.31640del p.K10547Rfs*17 (on ENST00000591111; = p.K9620Rfs*17 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/276 reads (23%) | catalogued as COSV60124124; called by mutect2, pindel, varscan2
- TUBA3E | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); catalogued as rs760795453, COSV99919812; called by mutect2, varscan2
- TXNRD1 | c.654del p.K218Nfs*2 (on ENST00000525566 / NM_001093771.3; = p.K120Nfs*2 on NM_003330.4) | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as rs34549800; called by mutect2, pindel, varscan2
- UGT2B7 | c.638del p.N213Ifs*2 | Frame Shift Del (DEL) | VAF 50/227 reads (22%) | catalogued as rs1369776133; called by mutect2, pindel, varscan2
- ULK1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs772152229; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs760213136; called by mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- USP20 | c.1661-1G>T p.X554_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | catalogued as rs374688989; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 142/256 reads (55%) | catalogued as rs572063854; called by mutect2, varscan2
- USP40 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs193176157; called by muse, mutect2, varscan2
- UTF1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs781313378; called by muse, mutect2, varscan2
- VIM | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs1452626097, COSV56406480; called by muse, mutect2
- VPS11 | c.476G>A p.R159Q (on ENST00000620429; = p.R703Q on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs202163179; called by muse, mutect2, varscan2
- VPS16 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs772620388, COSV66794319; called by muse, mutect2
- VPS9D1 | c.947del p.P316Rfs*93 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1452701539; called by mutect2, varscan2
- WDR25 | c.1413G>A p.K471= | Splice Region (SNP) | VAF 15/75 reads (20%) | catalogued as rs754324340; called by muse, mutect2, varscan2
- WDR27 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs931292408, COSV100358194; called by muse, mutect2, varscan2
- WDR97 | c.3439C>T p.R1147W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as rs781188668; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- YLPM1 | c.284del p.G95Afs*124 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs773058360; called by mutect2, varscan2
- ZDHHC4 | c.344del p.F115Sfs*3 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs34551853; called by mutect2, varscan2
- ZDHHC7 | c.831del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as COSV58214455; called by mutect2, pindel, varscan2
- ZG16 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.29); catalogued as rs752320426; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072dup p.N691Kfs*5 | Frame Shift Ins (INS) | VAF 54/269 reads (20%) | catalogued as rs556762260; called by mutect2, varscan2
- ZKSCAN7 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs767975850, COSV56272497; called by muse, mutect2, varscan2
- ZMIZ1 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs749056628; called by muse, mutect2, varscan2
- ZMIZ2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773245959, COSV54809757; called by muse, mutect2, varscan2
- ZMYM3 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV58737552; called by muse, mutect2, varscan2
- ZNF142 | c.1108C>T p.R370C (on ENST00000411696 / NM_001379660.1; = p.R170C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768640181, COSV68746740; called by muse, mutect2, varscan2
- ZNF143 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs372568844; called by muse, mutect2, varscan2
- ZNF254 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1352467651; called by muse, mutect2, varscan2
- ZNF268 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV99935110; called by muse, mutect2, varscan2
- ZNF284 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs750211263, COSV101399072, COSV69691640; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF408 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs773162748; called by muse, mutect2, varscan2
- ZNF417 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367963790; called by mutect2, varscan2
- ZNF423 | c.2558T>C p.V853A (on ENST00000563137 / NM_001379286.1; = p.V845A on NM_015069.4) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV99283497; called by muse, mutect2, varscan2
- ZNF446 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59990931; called by muse, mutect2, varscan2
- ZNF524 | c.174dup p.K59Qfs*31 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | catalogued as rs750719825; called by mutect2, varscan2
- ZNF630 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52095852; called by muse, mutect2, varscan2
- ZNF638 | c.3912del p.G1305Vfs*22 | Frame Shift Del (DEL) | VAF 65/231 reads (28%) | catalogued as rs1196097264; called by mutect2, varscan2
- ZNF660 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs572820848, COSV59549791, COSV59549853; called by muse, mutect2, varscan2
- ZNF672 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs557491045; called by muse, mutect2, varscan2
- ZNF780A | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61816127; called by muse, mutect2
- ZNRF1 | c.199del p.V67Cfs*96 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1555508498; called by mutect2, pindel, varscan2
- AAK1 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- AARD | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AATK | c.3100T>C p.S1034P (on ENST00000326724 / NM_001080395.3; = p.S931P on NM_004920.2) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- AATK | c.211del p.D71Tfs*58 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- ABCA1 | c.4728C>A p.S1576R | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2
- ABCB4 | c.3773A>G p.K1258R (on ENST00000265723 / NM_018849.3; = p.K1251R on NM_000443.4) | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB5 | c.847del p.R283Gfs*3 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1226del p.G409Efs*31 (on ENST00000297504 / NM_001282291.2; = p.G392Efs*31 on NM_007188.5) | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ABCC6 | c.1952T>A p.L651H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCD3 | c.163del p.E55Sfs*17 | Frame Shift Del (DEL) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- ABHD3 | c.625T>C p.Y209H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ACSL5 | c.1926del p.L643Ffs*13 (on ENST00000354273; = p.L699Ffs*13 on NM_016234.3) | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- ADAM17 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, varscan2
- ADCY1 | c.1425del p.F475Lfs*14 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.1711T>C p.Y571H | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRV1 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ADORA1 | c.575del p.P192Rfs*15 | Frame Shift Del (DEL) | VAF 44/104 reads (42%) | called by mutect2, pindel, varscan2
- ADRA2C | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.042); called by muse, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 74/296 reads (25%) | called by mutect2, varscan2
- AGO1 | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AGPS | c.1232A>G p.Q411R | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AGRN | c.1890del p.V631Cfs*101 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | called by mutect2, pindel, varscan2
- AGRN | c.3239del p.G1080Vfs*158 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- AGXT | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- AK9 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ALKBH7 | c.361del p.H121Tfs*80 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- ANK1 | c.2113_2114insA p.L705Hfs*88 | Frame Shift Ins (INS) | VAF 52/153 reads (34%) | called by mutect2, pindel, varscan2
- ANK2 | c.4818del p.A1607Hfs*3 | Frame Shift Del (DEL) | VAF 90/323 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.420del p.R141Afs*9 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- ANKS1A | c.2766C>A p.Y922* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- ANXA8 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AOC3 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- APBB1IP | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC2 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ARFGEF1 | c.3627del p.F1209Lfs*3 | Frame Shift Del (DEL) | VAF 67/205 reads (33%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP32 | c.4432A>G p.R1478G (on ENST00000310343 / NM_001378025.1; = p.R1129G on NM_014715.4) | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARHGAP6 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ARHGEF15 | c.359del p.P120Hfs*62 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF2 | c.1318dup p.A440Gfs*108 (on ENST00000361247 / NM_001162383.2; = p.A412Gfs*108 on NM_004723.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 46/273 reads (17%) | called by mutect2, pindel, varscan2
- ARMC4 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 134/466 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARVCF | c.1450C>A p.H484N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ASB6 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ASXL3 | c.714A>C p.L238F | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATAD2 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ATOH1 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2
- ATP12A | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ATP6V1F | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ATR | c.1338dup p.Q447Tfs*3 | Frame Shift Ins (INS) | VAF 60/224 reads (27%) | called by mutect2, pindel, varscan2
- ATXN2L | c.701del p.G234Vfs*33 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- AXIN2 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B4GALT6 | c.1075del p.I359Yfs*12 | Frame Shift Del (DEL) | VAF 53/142 reads (37%) | called by mutect2, pindel, varscan2
- BAAT | c.339A>G p.I113M | Missense Mutation (SNP) | VAF 108/421 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- BCL11B | c.1127C>T p.T376M (on ENST00000357195 / NM_001282237.2; = p.T305M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.196del p.I66Ffs*86 | Frame Shift Del (DEL) | VAF 40/223 reads (18%) | called by mutect2, pindel, varscan2
- BMPER | c.1175_1176del p.K392Rfs*112 | Frame Shift Del (DEL) | VAF 80/243 reads (33%) | called by mutect2, pindel, varscan2
- BRD3 | c.1202C>G p.A401G | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BRSK2 | c.1063del p.R355Gfs*4 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel, varscan2
- BRSK2 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- C16orf54 | c.486dup p.A163Rfs*9 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- C1orf94 | c.1495C>A p.H499N (on ENST00000488417 / NM_001134734.2; = p.H309N on NM_032884.5) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CA7 | c.449del p.L150Wfs*10 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1H | c.6021del p.S2008Vfs*39 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.1276A>G p.T426A (on ENST00000236925 / NM_001297707.2; = p.T415A on NM_203459.3) | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAND2 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- CAND2 | c.2051G>A p.G684D (on ENST00000456430 / NM_001162499.2; = p.G591D on NM_012298.3) | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CAPN6 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CARM1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 82/349 reads (23%) | called by mutect2, pindel, varscan2
- CASR | c.2499del p.S834Pfs*28 (on ENST00000490131; = p.S911Pfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- CASZ1 | c.5134G>A p.D1712N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); called by muse, varscan2
- CCAR1 | c.3202del p.T1068Pfs*3 | Frame Shift Del (DEL) | VAF 45/174 reads (26%) | called by mutect2, pindel, varscan2
- CCDC168 | c.5636A>C p.E1879A | Missense Mutation (SNP) | VAF 73/401 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CCDC168 | c.3346del p.M1116Wfs*8 | Frame Shift Del (DEL) | VAF 65/321 reads (20%) | called by mutect2, pindel, varscan2
- CCDC180 | c.2948A>G p.E983G | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- CCDC39 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CD5L | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD80 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 39/219 reads (18%) | called by mutect2, pindel, varscan2
- CDH15 | c.1695del p.Q566Sfs*10 | Frame Shift Del (DEL) | VAF 40/199 reads (20%) | called by mutect2, pindel, varscan2
- CDH26 | c.559A>T p.M187L | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH26 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5639del p.G1880Efs*43 | Frame Shift Del (DEL) | VAF 70/296 reads (24%) | called by pindel, varscan2
- CDK5RAP2 | c.3499dup p.E1167Gfs*29 | Frame Shift Ins (INS) | VAF 70/272 reads (26%) | called by mutect2, varscan2
- CDKAL1 | c.1341del p.F447Lfs*17 | Frame Shift Del (DEL) | VAF 64/130 reads (49%) | called by mutect2, pindel, varscan2
- CDKN1B | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- CELA1 | c.634dup p.C212Lfs*22 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- CEP170 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CEP350 | c.8666del p.N2889Ifs*10 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | called by mutect2, pindel, varscan2
- CFL2 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- CHAD | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CHD1 | c.929del p.N310Tfs*10 | Frame Shift Del (DEL) | VAF 50/228 reads (22%) | called by mutect2, pindel, varscan2
- CHEK1 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CIITA | c.1581del p.L528Cfs*30 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CKAP2 | c.455del p.N152Tfs*8 (on ENST00000378037 / NM_001098525.2; = p.N151Tfs*8 on NM_018204.5) | Frame Shift Del (DEL) | VAF 60/288 reads (21%) | called by mutect2, varscan2
- CLCN5 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLCN7 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | called by mutect2, varscan2
- CLTC | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNIH2 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CNTNAP5 | c.1153dup p.Q385Pfs*3 | Frame Shift Ins (INS) | VAF 69/300 reads (23%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.2988del p.E997Rfs*22 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- CNTRL | c.4792G>T p.V1598F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COASY | c.885del p.M296Wfs*23 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel, varscan2
- COG2 | c.2017A>C p.T673P | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- COL25A1 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL3A1 | c.3076G>A p.G1026R | Missense Mutation (SNP) | VAF 124/517 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COLGALT1 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COP1 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CPE | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CREBBP | c.4826G>A p.S1609N | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CREBBP | c.3953C>A p.P1318H | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CRIP3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by mutect2, varscan2
- CRTC1 | c.1735A>G p.S579G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CRYBG1 | c.2884C>T p.L962F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSGALNACT1 | c.1594del p.T532Hfs*43 | Frame Shift Del (DEL) | VAF 83/346 reads (24%) | called by mutect2, pindel, varscan2
- CSMD1 | c.6946T>C p.C2316R (on ENST00000520002; = p.C2315R on NM_033225.6) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSN1S1 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 92/318 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSNK1D | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CTNNB1 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX2 | c.2934del p.T979Qfs*24 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- CYBRD1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DAB1 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBX1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, varscan2
- DCDC1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2
- DCHS2 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, varscan2
- DDA1 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2
- DDR1 | c.1679del p.P560Hfs*93 (on ENST00000324771; = p.P523Hfs*93 on NM_001954.4) | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- DDR2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- DENND2B | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND2B | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DIP2A | c.3227A>G p.H1076R | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DMRTA1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRTA2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAH5 | c.1544T>C p.V515A | Missense Mutation (SNP) | VAF 45/584 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2
- DNAH6 | c.340del p.S114Vfs*16 | Frame Shift Del (DEL) | VAF 62/292 reads (21%) | called by mutect2, varscan2
- DNAH6 | c.6920T>C p.I2307T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DNAJA3 | c.1133dup p.G379Wfs*19 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- DNASE1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- DOCK1 | c.5407C>T p.P1803S | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOCK3 | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DOP1A | c.6086C>T p.T2029I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- DPH2 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- DPPA2 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRAXIN | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DSC2 | c.2508+2T>C p.X836_splice | Splice Site (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- DST | c.1089del p.K364Nfs*7 | Frame Shift Del (DEL) | VAF 54/215 reads (25%) | called by mutect2, pindel, varscan2
- DTX3L | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP29 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDNRB | c.457G>A p.A153T (on ENST00000377211 / NM_001201397.1; = p.A63T on NM_000115.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EEF1D | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EEFSEC | c.569del p.G190Dfs*20 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- ERO1A | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERO1A | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- EXOSC9 | c.234del p.F78Lfs*23 | Frame Shift Del (DEL) | VAF 50/198 reads (25%) | called by mutect2, varscan2
- EYS | c.4152dup p.P1385Sfs*2 | Frame Shift Ins (INS) | VAF 63/276 reads (23%) | called by mutect2, pindel, varscan2
- FAM117A | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM151A | c.1600del p.R534Gfs*18 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- FAM157A | n.133G>T | Splice Region (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2747G>A p.G916D (on ENST00000449352 / NM_001098794.2; = p.G930D on NM_032127.4) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
942 further variants in this file (377 protein-altering or splice-affecting, 351 silent, 214 other) are not listed here.
